Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3T1, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3T1-01A (Primary Tumor).

[page 1 of 2]
History Case Pathology Report

DOB:

Sex:

Physician:

Received:

Pathologist:

Accession:

Case type: Surgical History

**** Case imported from computer system. The format of this report does not match the original case. ****
**** For cases prior to section "SPECIMEN" may have been added. ****

DIAGNOSIS

(A) PARATHYROID, RULE OUT:

Parathyroid tissue.

(B) TOTAL THYROIDECTOMY:

PAPILLARY CARCINOMA OF THYROID WITH EXTENSION INTO ADJACENT CONNECTIVE TISSUE. THE TUMOR ABUTTS THE CAUTERIZED MARGIN. Separate small focus suggestive of papillary carcinoma involves the right thyroid lobe.

Hashimoto's thyroiditis.

One lymph node (0/1), negative for metastatic carcinoma.

Changes consistent with previous aspiration site.

(C) MASS AND TAIL OF RIGHT BREAST:

Fibroadenoma ("giant fibroadenoma").

Fibrocystic change.

(D) TISSUE OF RIGHT BREAST:

Proliferative fibrocystic change.

(E) MASS OF LEFT BREAST:

Fibroadenomatous hyperplasia.

Proliferative fibrocystic change.

ICD-O-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9 4-312 RD

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) PARATHYROID RULE OUT - A 0.2 x 0.1 x 0.1 cm portion of pink-tan tissue. Submitted entirely for frozen section in cassette A.

*FS/DX: PARATHYROID TISSUE.

(B) TOTAL THYROIDECTOMY - A 9.0 x 7.0 x 3.4 cm purple-tan thyroid. The left and right lobes are slightly lobulated and approximately equal in size. The isthmus is nodular and distorted by a 3.8 x 3.0 x 2.9 cm nodule.

The isthmus mass is pink-gray and firm. The tumor abuts but does not appear to extend through the confines of the thyroid gland. The remaining thyroid parenchyma is purple-tan and slightly congested. No additional mass lesions are identified. A representative sample is submitted for

INK CODE: Black - thyroid surface.

SECTION CODE: A representative sample of this specimen is submitted as follows: B1-B8, tumor submitted from left to right; B9-B11, representative sample of left lobe; B12-B14, representative sample of right lobe.

(C) MASS AND TAIL OF RIGHT BREAST - A 16.0 x 10.0 x 5.2 cm unoriented portion

[page 2 of 2]
History Case Pathology Report

Department of Pathology,

DOB:

Sex:

Physician:

Received

Pathologist:

Accession:

Case type: Surgical History

of yellow-tan fibroadipose tissue. The apparent tail of breast tissue is 9.0 x 6.0 x 3.5 cm and contains slightly fibrous breast parenchyma. No definite lymph nodes are identified. The remainder of the specimen consists of a roughly oval yellow-gray well-circumscribed mass which is 10.5 x 8.0 x 4.6 cm. The outer surface of the mass is smooth with a thin translucent capsule. The mass does not appear to infiltrate the adjacent parenchyma. There is no evidence of hemorrhage or necrosis. Representative sections are submitted for frozen section.

INK CODE:

Yellow-superficial,
Blue-superior,
Green-inferior,
Orange-medial,
Red-lateral,
Black-deep, and
Black-tail.

SECTION CODE: Representative sections submitted as follows: C1, deep margin with mass perpendicular section; C2, superficial margin with mass, perpendicular section; C3, inferior margin with mass perpendicular section; C4, central aspect of mass, no margin; C5, mass with superior margin; C6, mass with medial margin; C7, mass with lateral margin; C8, mass with lateral margin; C9, deep margin; C10, mass with superficial margin; C11, central aspect of mass; C12, C13, mass with inferior margin; C14, mass adjacent to inferior margin; C15, mass with medial; C16, mass with superior margin; C17-C20, tail.

*FS/DX: NO EVIDENCE OF MALIGNANCY.

(D) TISSUE RIGHT BREAST, FIBROCYSTIC VERSUS PHYLLODES - A 4.0 x 3.8 x 2.0 cm slightly nodular portion of yellow-tan fibroadipose tissue.

Multiple small fluid-filled cysts are identified. No discrete mass lesions are present. Representative section is submitted for frozen section.

INK CODE: Black-margin.

SECTION CODE: D1 frozen section; D2-D13, remainder of specimen submitted sequentially.

*FS/DX: FIBROCYSTIC CHANGE.

(E) MASS LEFT BREAST, FIBROCYSTIC VERSUS PHYLLODES - A 10.0 x 9.0 x 8.4 cm slightly lobulated portion of firm yellow-tan fibrofatty breast tissue. No orientation is provided. No lymph nodes are identified.

A 1.5 x 1.0 x 0.8 cm pink-tan well-circumscribed nodule is identified along one aspect of the specimen. The nodule approaches to within 0.4 cm of the peripheral margin. The remaining breast parenchyma is fibrofatty with multiple gray-brown cysts. No additional mass lesions are identified.

INK CODE: Black = margin.

SECTION CODE: A representative sections including entire nodule submitted as follows: E1-E3, nodule; E4-E9, representative sections from remainder of specimen.

CONSULTATION

SNOMED CODES

M-80503 M-90100 M-H0310 T-04050 T-B6000

Source: NCI Genomic Data Commons file 0fc3e9d5-2c36-4a82-a3c8-3e3fab1fe9e5 (TCGA-EL-A3T1.9801ADBD-282E-494E-B703-BD1DB5CE4FC5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).